Somatic mutation profile of tumor specimen TCGA-G9-6494-01A (aliquot TCGA-G9-6494-01A-11D-1786-08) from TCGA case TCGA-G9-6494, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.8 years (24,381 days).
Specimen TCGA-G9-6494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf4400a9-fe66-42ba-86aa-78678f290d8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6494-10A (Blood Derived Normal), aliquot TCGA-G9-6494-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7c98d40-0cf1-4bfa-be92-98683b075848

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Del 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA | c.99G>T p.R33S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV65740261; called by muse, mutect2, varscan2
- ANO3 | c.1575G>T p.E525D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as rs1565133426, COSV56795574; called by muse, mutect2, varscan2
- ARID3A | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708333; called by muse, varscan2
- BMP2K | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV58596215; called by muse, mutect2, varscan2
- CCDC57 | c.1814A>G p.D605G | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV58935738; called by muse, mutect2
- DNAAF5 | c.1382G>C p.R461P | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV52418068; called by muse, mutect2, varscan2
- FOXL1 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1310647716, COSV100206456, COSV57214573; called by muse, mutect2, varscan2
- GLP2R | c.324T>A p.H108Q | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV52326169; called by muse, mutect2
- IGDCC4 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs749510394, COSV61535560; called by muse, mutect2, varscan2
- MTREX | c.1227A>C p.L409F | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV57927008; called by muse, mutect2, varscan2
- MUC16 | c.23086G>A p.V7696M | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs770085186, COSV101198328, COSV67474468; called by muse, mutect2, varscan2
- MYH4 | c.2938A>C p.K980Q | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55120275, COSV55122176; called by muse, mutect2, varscan2
- PCDH11Y | c.1253C>T p.T418M (on ENST00000400457 / NM_032973.2; = p.T407M on NM_032971.3) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV53072638; called by muse, mutect2, varscan2
- PFN2 | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV53524072; called by muse, mutect2, varscan2
- QKI | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV51696337; called by muse, mutect2, varscan2
- RWDD2A | c.416A>T p.K139M | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV52284474; called by muse, mutect2, varscan2
- TNFAIP3 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV52799735; called by muse, mutect2, varscan2
- TPX2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as COSV55920316, COSV55920647; called by muse, mutect2, varscan2
- TSHR | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.404); catalogued as rs1276734165, COSV53322988; called by muse, mutect2, varscan2
- ZNF214 | c.1417C>G p.P473A | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53482441; called by muse, mutect2, varscan2
- ERCC6 | c.623_627del p.L208Pfs*57 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- KLK2 | c.304_305del p.N102Yfs*10 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- RC3H1 | c.1103-3_1103-2dup p.X368_splice | Splice Site (INS) | VAF 8/71 reads (11%) | called by mutect2, pindel, varscan2
- SFI1 | c.2409del p.K804Rfs*97 (on ENST00000400288 / NM_001007467.3; = p.K773Rfs*97 on NM_014775.4) | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- CEP170B | c.750G>A p.T250= (on ENST00000453495; = p.T179= on NM_015005.3) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs375437438; called by muse, mutect2, varscan2
- LBP | c.37C>T p.L13= | Silent (SNP) | VAF 12/135 reads (9%) | catalogued as rs750735863, COSV54141043; called by muse, mutect2
- SIX2 | c.636G>A p.S212= | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as rs371909390, COSV57390293; called by muse, mutect2, varscan2
- SLC16A10 | c.627C>T p.G209= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV64354496; called by muse, mutect2, varscan2
- TOP2A | c.3351C>A p.S1117= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV70732053, COSV70732805; called by muse, mutect2, varscan2
- TRGC1 | c.27C>T p.S9= | Silent (SNP) | VAF 87/303 reads (29%) | called by muse, mutect2, varscan2
